Somatic mutation profile of tumor specimen C3N-03486-03 (aliquot CPT0195510009) from CPTAC case C3N-03486, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 65.3 years (23,849 days).
Specimen C3N-03486-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3e12a0b-6b2f-4b47-855a-122b1d238b8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03486-71 (Blood Derived Normal), aliquot CPT0195610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b842f24b-a83b-4177-bd67-3619ede013a4

The open-access MAF lists 543 somatic variants for this specimen: 365 protein-altering or splice-affecting, 110 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 304, Silent 110, Intron 35, Nonsense Mutation 28, Splice Site 13, RNA 13, 3'UTR 9, Frame Shift Del 8, 5'UTR 7, Splice Region 5, Frame Shift Ins 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>T p.X51_splice | Splice Site (SNP) | VAF 143/425 reads (34%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by mutect2, varscan2
- SMAD4 | c.1067C>G p.P356R | Missense Mutation (SNP) | VAF 37/169 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685209, COSV61685537, COSV61689602; called by muse, mutect2, varscan2
- TP53 | c.1010G>C p.R337P | Missense Mutation (SNP) | VAF 60/306 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHSG | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321644126; called by muse, mutect2, varscan2
- ANGPTL4 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 98/624 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56845732; called by muse, mutect2, varscan2
- ARHGAP35 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 36/276 reads (13%) | catalogued as COSV101350595; called by muse, mutect2, varscan2
- ARHGAP9 | c.1852G>C p.D618H (on ENST00000393797 / NM_001319850.2; = p.D599H on NM_032496.4) | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57361841, COSV57366220, COSV99954177; called by muse, mutect2, varscan2
- ATP1A3 | c.2009del p.G670Afs*48 (on ENST00000545399 / NM_001256214.2; = p.G657Afs*48 on NM_152296.5) | Frame Shift Del (DEL) | VAF 232/777 reads (30%) | catalogued as COSV57491276; called by mutect2, pindel, varscan2
- BASP1 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.291); catalogued as COSV100493659; called by muse, mutect2, varscan2
- C2CD3 | c.5014G>A p.D1672N | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs139653763; called by muse, mutect2
- C3orf56 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV67756368; called by muse, mutect2, varscan2
- C4orf54 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 77/416 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.911); catalogued as rs1468765798; called by muse, varscan2
- C8orf37 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs115660509; called by muse, mutect2, varscan2
- C9orf40 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 48/295 reads (16%) | catalogued as COSV100964975, COSV100964989; called by muse, mutect2, varscan2
- CAVIN1 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 75/339 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV63811537; called by muse, mutect2, varscan2
- CCT8 | c.1640A>G p.N547S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54505647; called by muse, mutect2
- CD200R1L | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs761769569; called by muse, mutect2, varscan2
- CEACAM8 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 25/472 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV54991411; called by muse, mutect2
- CEP128 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.718); catalogued as COSV53676015; called by muse, mutect2, varscan2
- CHD4 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV58902562; called by muse, mutect2
- CNTNAP5 | c.2660C>A p.S887Y | Missense Mutation (SNP) | VAF 77/435 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV70477774; called by muse, mutect2, varscan2
- COL1A2 | c.2348C>A p.P783H | Missense Mutation (SNP) | VAF 88/524 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99799772; called by muse, mutect2, varscan2
- COL22A1 | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1280843879; called by muse, mutect2, varscan2
- CRTC1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100119290; called by muse, mutect2, varscan2
- CTTNBP2 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751681284; called by muse, mutect2
- CUL3 | c.1378-1G>C p.X460_splice | Splice Site (SNP) | VAF 22/109 reads (20%) | catalogued as COSV52362106, COSV52363563; called by muse, mutect2, varscan2
- DAPK1 | c.4286C>A p.S1429Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100802577; called by muse, varscan2
- DCTN3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs571645079; called by muse, mutect2, varscan2
- DMD | c.6352C>A p.Q2118K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.709); catalogued as CM098434, COSV100822077; called by muse, mutect2, varscan2
- DNAH5 | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 128/497 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs141072655; called by muse, mutect2, varscan2
- DNAJB14 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs1375998576; called by muse, varscan2
- DQX1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.96); catalogued as rs1014984499; called by muse, mutect2, varscan2
- EBF1 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV58172430; called by muse, mutect2, varscan2
- EIF4G1 | c.3732G>C p.K1244N (on ENST00000346169 / NM_198241.3; = p.K1049N on NM_004953.5) | Missense Mutation (SNP) | VAF 72/800 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100072091; called by muse, mutect2
- ELMO1 | c.2101C>G p.L701V | Missense Mutation (SNP) | VAF 75/451 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV60314095; called by muse, mutect2, varscan2
- ELP1 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as rs765376716; called by muse, mutect2, varscan2
- EXTL3 | c.560G>C p.R187P | Missense Mutation (SNP) | VAF 108/493 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55036850, COSV99593898; called by muse, mutect2, varscan2
- FAM47B | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs1385838832; called by muse, mutect2, varscan2
- FAT3 | c.9440A>C p.K3147T | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs369657341; called by muse, mutect2, varscan2
- FH | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755587163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSHR | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58619867; called by muse, mutect2, varscan2
- FZR1 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 60/374 reads (16%) | catalogued as COSV58052305; called by muse, mutect2, varscan2
- GFY | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1331228331; called by muse, mutect2, varscan2
- GGH | c.377A>T p.D126V | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs1241554752; called by muse, mutect2, varscan2
- GLDC | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58676401, COSV58683983; called by muse, mutect2, varscan2
- GLIS2 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 19/491 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs751071757; called by muse, mutect2
- HAS1 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 83/438 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV55787497; called by muse, mutect2, varscan2
- HCN1 | c.850-1G>T p.X284_splice | Splice Site (SNP) | VAF 22/161 reads (14%) | catalogued as COSV100299528, COSV57494929; called by muse, mutect2, varscan2
- HDGFL2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1040282892; called by muse, mutect2, varscan2
- HRNR | c.1857G>C p.Q619H | Missense Mutation (SNP) | VAF 258/1119 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as rs879042143; called by muse, mutect2, varscan2
- HTR1F | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs1364268349; called by muse, mutect2, varscan2
- KCND2 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as COSV58578297; called by muse, mutect2, varscan2
- KDR | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV55773771; called by muse, mutect2, varscan2
- KHDC1 | c.206+4C>A | Splice Region (SNP) | VAF 18/185 reads (10%) | catalogued as rs777358614; called by muse, mutect2, varscan2
- KIAA1755 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 88/479 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54076250; called by muse, mutect2, varscan2
- KRT4 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs1265492277; called by muse, mutect2, varscan2
- KRT75 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 76/590 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1454199281; called by muse, mutect2, varscan2
- LEPR | c.704-1G>T p.X235_splice | Splice Site (SNP) | VAF 21/94 reads (22%) | catalogued as rs1289160195, COSV60767895; called by muse, mutect2, varscan2
- LHB | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 130/491 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV55484352; called by muse, mutect2, varscan2
- LRCH2 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV57753497, COSV57756849; called by muse, mutect2, varscan2
- MAGEC1 | c.2053G>T p.G685W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); catalogued as COSV53567727; called by muse, mutect2, varscan2
- ME1 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 42/210 reads (20%) | catalogued as rs1352317774; called by muse, mutect2, varscan2
- MT3 | c.153C>A p.C51* | Nonsense Mutation (SNP) | VAF 66/417 reads (16%) | catalogued as COSV52365556; called by muse, mutect2, varscan2
- MYO6 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV64121190; called by muse, mutect2, varscan2
- MYPN | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 64/391 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62741578; called by muse, mutect2, varscan2
- NAP1L5 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV52021642; called by muse, mutect2, varscan2
- NAXD | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 55/152 reads (36%) | catalogued as rs1290618678; called by muse, mutect2, varscan2
- NFKBID | c.883G>C p.E295Q (on ENST00000396901; = p.E447Q on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV100573202, COSV61728149; called by muse, mutect2, varscan2
- NPHP3 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 53/332 reads (16%) | catalogued as rs148670389; called by muse, mutect2, varscan2
- OR10A5 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748546572, COSV55053399; called by muse, mutect2, varscan2
- OR2L2 | c.361C>G p.R121G | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV63548141; called by muse, mutect2, varscan2
- OR52R1 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1434425411; called by muse, mutect2, varscan2
- OR5D14 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1459988977, COSV100162258; called by muse, mutect2, varscan2
- ORC6 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 74/448 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767757249; called by muse, mutect2, varscan2
- PDGFC | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99925567; called by muse, mutect2, varscan2
- PDHA2 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54782458; called by muse, mutect2, varscan2
- PDZD4 | c.1885C>A p.R629S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV51246768; called by muse, mutect2, varscan2
- PEX5L | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV99828948; called by muse, mutect2, varscan2
- PHF24 | c.1162C>G p.R388G | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54273085; called by mutect2, varscan2
- PIGR | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1227811946; called by muse, mutect2, varscan2
- PIK3CA | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV55889750, COSV55906105, COSV56009988; called by muse, mutect2, varscan2
- PIK3IP1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV53224522; called by muse, mutect2, varscan2
- PLD1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.276); catalogued as rs948429724; called by muse, mutect2
- PRSS38 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 76/579 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs769609550, COSV64539745; called by muse, mutect2, varscan2
- PWWP2B | c.1425G>C p.Q475H | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs138536011; called by muse, mutect2, varscan2
- RAB11FIP2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.815); catalogued as rs1263276105; called by muse, mutect2, varscan2
- RANBP17 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148543415; called by muse, mutect2, varscan2
- RANBP3L | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs904536484; called by muse, mutect2, varscan2
- RIMBP2 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 202/551 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55476838; called by muse, mutect2, varscan2
- RNASEL | c.2135A>G p.Y712C | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs575231428; called by muse, mutect2, varscan2
- SERPINB4 | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 47/244 reads (19%) | catalogued as rs776207758, COSV61984891, COSV61985864; called by muse, mutect2, varscan2
- SHISA4 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1354360403; called by muse, mutect2, varscan2
- SLC10A2 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55358350, COSV99807879; called by muse, mutect2, varscan2
- SLC29A1 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as rs1234755791; called by muse, mutect2, varscan2
- SLCO1A2 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV56598723; called by muse, mutect2, varscan2
- SLIT1 | c.3587C>A p.T1196K | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56589657; called by muse, mutect2, varscan2
- SLITRK1 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV65674062, COSV65674512; called by muse, mutect2, varscan2
- SPATA5L1 | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99973102; called by muse, mutect2, varscan2
- SPEG | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV100403792; called by muse, mutect2, varscan2
- SPP1 | c.576C>A p.H192Q (on ENST00000395080 / NM_001040058.2; = p.H178Q on NM_000582.2) | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as rs767926035; called by muse, mutect2
- SPTBN4 | c.2722C>A p.R908S | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.38); catalogued as COSV58949170; called by muse, mutect2, varscan2
- STPG2 | c.773-1G>T p.X258_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV54787655; called by muse, mutect2, varscan2
- TBC1D9B | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs574734327; called by muse, mutect2, varscan2
- TCERG1L | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs745750215; called by muse, mutect2
- TLR5 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553763265, COSV60559121; called by muse, mutect2, varscan2
- TMEM229A | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV71900426; called by muse, mutect2
- TRAF3IP1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV100966854; called by muse, mutect2, varscan2
- TRAF4 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781098705; called by muse, mutect2
- TRAPPC1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs762780173; called by muse, mutect2, varscan2
- TRDN | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV62114514, COSV62136234; called by muse, varscan2
- TTN | c.11050C>A p.P3684T (on ENST00000591111; = p.P3638T on NM_003319.4) | Missense Mutation (SNP) | VAF 39/204 reads (19%) | catalogued as rs1320141997; called by muse, mutect2, varscan2
- UTP20 | c.3778C>G p.L1260V | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV55376477; called by muse, mutect2, varscan2
- VASP | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs568311975, COSV55606531; called by muse, mutect2, varscan2
- VCAN | c.2323G>C p.G775R | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.184); catalogued as COSV99424568; called by muse, mutect2, varscan2
- VEPH1 | c.1898C>G p.S633C | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs768281517, COSV62876430; called by muse, mutect2, varscan2
- ZER1 | c.858C>G p.I286M | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV99401986; called by mutect2, varscan2
- ZNF827 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs773093381, COSV101061723; called by muse, mutect2, varscan2
- ZNF99 | c.1655T>C p.L552P | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV68055961, COSV68056476; called by muse, mutect2
- ABCA3 | c.4291G>T p.G1431W | Missense Mutation (SNP) | VAF 83/440 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB6 | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ABCC12 | c.3217T>C p.C1073R | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- AC098582.1 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- ACTL7A | c.956C>A p.S319* | Nonsense Mutation (SNP) | VAF 47/255 reads (18%) | called by muse, mutect2, varscan2
- ACTR1B | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 112/667 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ADAD1 | c.42dup p.S15Qfs*45 | Frame Shift Ins (INS) | VAF 27/151 reads (18%) | called by mutect2, pindel, varscan2
- AGAP2 | c.2383C>A p.H795N (on ENST00000547588 / NM_001122772.2; = p.H459N on NM_014770.4) | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.13321A>G p.K4441E | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- AKR1D1 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMBRA1 | c.2828A>T p.N943I (on ENST00000458649 / NM_001367468.1; = p.N853I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMER3 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ARFGEF3 | c.1337T>C p.L446S | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ARHGAP31 | c.2525G>C p.R842T | Missense Mutation (SNP) | VAF 107/748 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ASIC5 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATP10A | c.4158G>T p.E1386D | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B4 | c.2018T>C p.L673P | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AXDND1 | c.2491G>T p.E831* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- BICC1 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 31/159 reads (19%) | called by muse, varscan2
- BRD4 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- BRINP3 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, varscan2
- BRINP3 | c.1814T>A p.L605Q | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.462); called by muse, varscan2
- C4orf54 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); called by muse, varscan2
- C7 | c.1877G>T p.C626F | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CA14 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- CACNA1H | c.3440G>A p.S1147N | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- CACNA2D1 | c.2761G>T p.V921L (on ENST00000356253 / NM_001366867.1; = p.V909L on NM_000722.4) | Missense Mutation (SNP) | VAF 64/361 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CCBE1 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 33/466 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.079); called by muse, mutect2
- CCDC14 | c.1922A>G p.D641G (on ENST00000488653; = p.D593G on NM_022757.5) | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2
- CCDC188 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- CCDC39 | c.1288C>A p.L430M | Missense Mutation (SNP) | VAF 131/240 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CCDC68 | c.605A>T p.K202M | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCN5 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCNE2 | c.1076C>A p.T359K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CCT5 | c.227_234del p.T76Kfs*6 | Frame Shift Del (DEL) | VAF 105/331 reads (32%) | called by mutect2, pindel, varscan2
- CDH10 | c.1344C>A p.D448E | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- CDH18 | c.900T>A p.N300K | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH19 | c.1828+1G>A p.X610_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | called by muse, varscan2
- CDH2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CEACAM16 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 50/402 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CELF4 | c.1099+2T>A p.X367_splice | Splice Site (SNP) | VAF 53/264 reads (20%) | called by muse, mutect2, varscan2
- CHRNA10 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CHST6 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CLVS2 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CNGA4 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CNTNAP4 | c.2996-1G>T p.X999_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- COL6A6 | c.6777del p.K2260Nfs*26 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- CT45A1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 83/1099 reads (8%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTNND2 | c.944C>A p.S315* | Nonsense Mutation (SNP) | VAF 86/583 reads (15%) | called by muse, mutect2, varscan2
- CWH43 | c.1349C>G p.S450* | Nonsense Mutation (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- DGLUCY | c.1279A>T p.R427* | Nonsense Mutation (SNP) | VAF 64/255 reads (25%) | called by muse, mutect2, varscan2
- DHX9 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.248); called by muse, mutect2
- DNMBP | c.3217G>A p.G1073R | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DOCK1 | c.1820T>G p.L607R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DOCK10 | c.1835C>G p.T612S | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBF3 | c.1561+2T>A p.X521_splice (on ENST00000355311 / NM_001375392.1; = p.X512_splice on NM_001005463.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- EFHD2 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 55/331 reads (17%) | called by muse, mutect2, varscan2
- EGF | c.1829del p.K610Rfs*27 | Frame Shift Del (DEL) | VAF 24/151 reads (16%) | called by mutect2, pindel, varscan2
- EIF6 | c.372G>A p.E124= | Splice Region (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- ELMO1 | c.243+4A>T | Splice Region (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- EMID1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 163/450 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ENTR1 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA5 | c.2658T>A p.D886E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EXTL1 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EYS | c.4571G>T p.S1524I | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EYS | c.1986G>T p.R662S | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM135B | c.3260A>T p.E1087V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FAT3 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN3 | c.1459T>G p.C487G | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO47 | c.659G>T p.R220M | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FCRL2 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- FH | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2
- FKBP11 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FOXJ3 | c.831A>C p.E277D | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- GFAP | c.1291+4A>G | Splice Region (SNP) | VAF 31/177 reads (18%) | called by muse, mutect2
- GIMAP8 | c.1418T>A p.V473D | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GOLGA8S | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 24/610 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- GPC6 | c.1343A>G p.E448G | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK4 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GTF2H1 | c.248G>T p.S83I | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GYG1 | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HBE1 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HDAC4 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 90/652 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- HDHD3 | c.251A>T p.H84L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECW2 | c.4255G>C p.V1419L | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- HIF3A | c.1650C>A p.S550R (on ENST00000377670 / NM_152795.4; = p.S481R on NM_022462.4) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- HIVEP1 | c.8002C>T p.H2668Y | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- HOXA10 | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPB8 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 177/592 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- HYDIN | c.5748G>T p.Q1916H | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IGHE | c.449T>A p.L150Q | Missense Mutation (SNP) | VAF 79/442 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL17REL | c.139A>G p.M47V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL1RAPL2 | c.288A>T p.K96N | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- INPP4A | c.2156_2167+18del p.X719_splice (on ENST00000074304 / NM_001134224.1; = p.X680_splice on NM_001566.2 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 26/152 reads (17%) | called by mutect2, pindel
- INVS | c.3082C>T p.L1028F | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- IPO9 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2
- IRX4 | c.1558T>A p.*520Rext*44 | Nonstop Mutation (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- ITFG1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA8 | c.892-1G>A p.X298_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- ITPRID1 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- IWS1 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- JMJD1C | c.5352G>A p.M1784I | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- KCNH7 | c.1801G>C p.D601H | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- KCNK4 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KCTD3 | c.1183G>T p.G395* | Nonsense Mutation (SNP) | VAF 56/208 reads (27%) | called by muse, mutect2, varscan2
- KIAA0586 | c.4484T>C p.M1495T (on ENST00000619416 / NM_001244190.2; = p.M1434T on NM_014749.5) | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1522 | c.2039C>T p.P680L (on ENST00000373480 / NM_001198972.2; = p.P739L on NM_020888.3) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KIF18A | c.2432T>C p.M811T | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIR3DL2 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KPRP | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LBP | c.55T>A p.S19T | Missense Mutation (SNP) | VAF 80/482 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LCE1C | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 99/388 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LIMK1 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LPA | c.2784A>T p.Q928H | Missense Mutation (SNP) | VAF 75/519 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LRCH2 | c.923G>C p.R308T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- LRFN5 | c.397A>G p.N133D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.13477C>A p.P4493T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- LRTM2 | c.291_309delinsA p.D98_F103del | In Frame Del (DEL) | VAF 94/415 reads (23%) | called by pindel, varscan2*
- LY6L | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- LZTS1 | c.936A>T p.K312N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MACF1 | c.19816G>A p.D6606N (on ENST00000372915; = p.D4651N on NM_012090.5) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- MAGEC2 | c.597A>T p.E199D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MAGI1 | c.3274G>A p.G1092R (on ENST00000402939 / NM_001033057.2; = p.G1121R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- MAP2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K21 | c.2300C>A p.A767D | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- MAPK8IP2 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 104/470 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- MARCHF6 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MARCHF6 | c.420G>T p.L140F | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MDN1 | c.6546G>T p.Q2182H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2
- MEP1A | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MGAT4C | c.840T>A p.Y280* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- MMRN2 | c.1802A>G p.E601G | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- MUC16 | c.7115A>G p.D2372G | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MYH9 | c.2224C>G p.L742V | Missense Mutation (SNP) | VAF 84/491 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NCDN | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 81/426 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- NEB | c.15054+2T>A p.X5018_splice | Splice Site (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- NLRP3 | c.733A>C p.T245P | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by mutect2, varscan2
- NME8 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2
- NRXN1 | c.4030A>T p.I1344F | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUDT16 | c.249A>C p.E83D | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP155 | c.1347+1G>C p.X449_splice (on ENST00000231498 / NM_153485.3; = p.X390_splice on NM_004298.4) | Splice Site (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- OAS3 | c.827A>C p.E276A | Missense Mutation (SNP) | VAF 122/339 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- OLFM3 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- OR11G2 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR4K5 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 43/508 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.367); called by muse, mutect2
- OR4Q3 | c.939A>T p.K313N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, varscan2
- OR56B1 | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 82/496 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR8H3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OSTM1 | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PA2G4 | c.1096del p.T366Pfs*22 | Frame Shift Del (DEL) | VAF 31/196 reads (16%) | called by mutect2, pindel, varscan2
- PADI6 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PAK2 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- PAPOLG | c.1932G>C p.K644N | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP14 | c.3118G>T p.V1040L | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDH11X | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH11X | c.2339C>A p.T780K | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDH15 | c.5008T>A p.S1670T | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PDE1A | c.1022A>T p.N341I | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE4DIP | c.5440A>G p.M1814V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.015); called by mutect2, varscan2
- PDGFRA | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDK4 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- PEG10 | c.375G>T p.M125I (on ENST00000482108 / NM_001040152.2; = p.M159I on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PHEX | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- PHLDB2 | c.2806G>A p.G936R (on ENST00000393925 / NM_001134439.2; = p.G893R on NM_145753.2) | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PIEZO2 | c.5188G>C p.A1730P | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PKHD1 | c.10188C>A p.Y3396* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- PKHD1 | c.4629G>T p.L1543F | Missense Mutation (SNP) | VAF 77/425 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PKP2 | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 65/427 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- POTEA | c.509A>T p.H170L | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- PRAMEF19 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 99/548 reads (18%) | called by muse, mutect2, varscan2
- PRB4 | c.529del p.R177Dfs*80 | Frame Shift Del (DEL) | VAF 63/221 reads (29%) | called by mutect2, pindel, varscan2
- PRKAR2B | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKG1 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- PRPF40A | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PSMC5 | c.662A>G p.Q221R | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RAB6C | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RAD21L1 | c.1011G>C p.W337C | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RC3H1 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RCAN2 | c.407T>G p.L136R | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RELN | c.7319G>C p.R2440T | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- REV3L | c.8818C>G p.R2940G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX4 | c.1510G>T p.A504S (on ENST00000392842 / NM_213594.3; = p.A410S on NM_032491.6) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RGS13 | c.105dup p.E36* | Frame Shift Ins (INS) | VAF 15/157 reads (10%) | called by mutect2, pindel
- RHPN2 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 55/395 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSF1 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SACS | c.9612A>T p.K3204N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SBNO2 | c.2864G>T p.G955V | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEC31A | c.2985G>A p.W995* (on ENST00000355196 / NM_001318120.1; = p.W956* on NM_016211.4) | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- SF3B1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SFXN4 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2
- SHROOM2 | c.1650G>T p.Q550H | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHROOM2 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 57/128 reads (45%) | called by muse, mutect2, varscan2
- SI | c.5223A>C p.L1741F | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SLC11A1 | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLC2A13 | c.1333T>C p.C445R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC39A12 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC5A9 | c.377T>A p.V126D | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC6A19 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 204/708 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLCO1B1 | c.1158del p.F386Lfs*7 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- SMCO3 | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA3 | c.1541A>T p.Q514L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- SPAG16 | c.1613G>T p.C538F | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SYNE1 | c.23719G>A p.E7907K (on ENST00000367255 / NM_182961.4; = p.E7836K on NM_033071.3) | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.20660A>T p.Q6887L (on ENST00000367255 / NM_182961.4; = p.Q6816L on NM_033071.3) | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TBC1D5 | c.1815G>T p.M605I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TCP11L2 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 98/526 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TECPR2 | c.3775G>C p.E1259Q | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TENM1 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TEX13C | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TGM2 | c.1491C>A p.N497K | Missense Mutation (SNP) | VAF 109/645 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIAM1 | c.4221C>A p.S1407R | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2
- TPBG | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TRABD | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRPC3 | c.2103G>T p.L701F (on ENST00000379645 / NM_001366479.2; = p.L628F on NM_003305.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC3 | c.2147C>G p.P716R | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTLL2 | c.699T>A p.F233L | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TTN | c.49853A>G p.E16618G (on ENST00000591111; = p.E9194G on NM_003319.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TTN | c.29808T>G p.I9936M (on ENST00000591111; = p.I9009M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TTN | c.12788C>A p.S4263Y (on ENST00000591111; = p.S4217Y on NM_003319.4) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.5067G>T p.W1689C (on ENST00000591111; = p.W1643C on NM_003319.4) | Missense Mutation (SNP) | VAF 43/216 reads (20%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TYMP | c.1177C>G p.R393G | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.255); called by muse, mutect2
- TYR | c.1498T>C p.C500R | Missense Mutation (SNP) | VAF 97/473 reads (21%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UBQLNL | c.1216T>C p.S406P | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBQLNL | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- UNC80 | c.9049C>A p.P3017T | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.14084C>A p.T4695K | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- VARS2 | c.2038-5C>T | Splice Region (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- WASHC2A | c.3239G>T p.R1080L | Missense Mutation (SNP) | VAF 155/883 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WDR49 | c.738G>C p.K246N (on ENST00000308378 / NM_001366158.1; = p.K587N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2
- WDR7 | c.2630A>T p.K877M | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- XRN1 | c.3094A>G p.T1032A | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP14 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- ZFP14 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ZFP14 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, varscan2
- ZFYVE9 | c.4081A>T p.K1361* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- ZIM2 | c.677C>G p.S226* | Nonsense Mutation (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- ZNF138 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 74/366 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF451 | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF493 | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ZNF518A | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF695 | c.959G>T p.R320I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF703 | c.1441_1452del p.L481_H484del | In Frame Del (DEL) | VAF 60/626 reads (10%) | called by mutect2, pindel
- ZNF786 | c.2111_2112del p.F704Sfs*4 | Frame Shift Del (DEL) | VAF 88/599 reads (15%) | called by mutect2, pindel, varscan2
- ZNF804B | c.1481T>C p.L494P | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF91 | c.652dup p.T218Nfs*10 | Frame Shift Ins (INS) | VAF 9/84 reads (11%) | called by mutect2, pindel, varscan2
- A1BG | c.1260C>T p.V420= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- ACAP2 | c.264A>G p.Q88= | Silent (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- ALKBH3 | c.831C>G p.V277= | Silent (SNP) | VAF 43/231 reads (19%) | catalogued as rs1307106729; called by muse, mutect2, varscan2
- ANKS1B | c.3597C>G p.S1199= (on ENST00000547776 / NM_152788.4; = p.S365= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/347 reads (13%) | called by muse, mutect2, varscan2
- ATP10A | c.2403C>T p.N801= | Silent (SNP) | VAF 42/239 reads (18%) | catalogued as rs779579438, COSV100791408, COSV63526753; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3534G>C p.S1178= | Silent (SNP) | VAF 67/202 reads (33%) | catalogued as COSV100864008; called by muse, mutect2, varscan2
- BLMH | c.1008G>A p.L336= | Silent (SNP) | VAF 36/291 reads (12%) | called by muse, mutect2, varscan2
- BMP3 | c.915A>G p.A305= | Silent (SNP) | VAF 39/234 reads (17%) | catalogued as COSV51082598; called by muse, mutect2, varscan2
- C20orf27 | c.129C>T p.V43= (on ENST00000379772 / NM_001258429.2; = p.V68= on NM_001039140.3) | Silent (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- C7orf31 | c.303C>T p.T101= | Silent (SNP) | VAF 37/236 reads (16%) | called by muse, mutect2, varscan2
- CACNA1S | c.5010T>C p.Y1670= | Silent (SNP) | VAF 65/411 reads (16%) | catalogued as rs1220958579; called by muse, mutect2, varscan2
- CALHM6 | c.195C>G p.L65= | Silent (SNP) | VAF 52/221 reads (24%) | called by muse, mutect2, varscan2
- CCDC28B | c.45C>A p.A15= | Silent (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- CCDC81 | c.1494G>T p.L498= (on ENST00000445632 / NM_001156474.2; = p.L408= on NM_021827.4) | Silent (SNP) | VAF 44/291 reads (15%) | called by muse, mutect2, varscan2
- CDR2L | c.564G>A p.L188= | Silent (SNP) | VAF 73/379 reads (19%) | called by muse, mutect2, varscan2
- CILP2 | c.1767C>T p.G589= | Silent (SNP) | VAF 53/225 reads (24%) | catalogued as rs149850801; called by muse, mutect2, varscan2
- CNOT6 | c.978T>C p.I326= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, varscan2
- CNTN3 | c.1908G>T p.R636= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- COL11A1 | c.3360C>A p.G1120= | Silent (SNP) | VAF 43/239 reads (18%) | catalogued as COSV104421794; called by muse, mutect2, varscan2
- COL22A1 | c.6C>T p.A2= | Silent (SNP) | VAF 120/377 reads (32%) | catalogued as rs147567223; called by muse, mutect2, varscan2
- CYFIP2 | c.1956G>A p.L652= (on ENST00000616178 / NM_001291722.2; = p.L627= on NM_014376.4) | Silent (SNP) | VAF 36/238 reads (15%) | catalogued as rs1221998459; called by muse, mutect2, varscan2
- CYSRT1 | c.408C>T p.R136= (on ENST00000409414; = p.R96= on NM_199001.5) | Silent (SNP) | VAF 91/427 reads (21%) | called by muse, mutect2, varscan2
- DLGAP5 | c.1221C>A p.G407= | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- ECEL1 | c.187C>T p.L63= | Silent (SNP) | VAF 43/262 reads (16%) | called by muse, mutect2, varscan2
- EEPD1 | c.645C>A p.A215= | Silent (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- EHD4 | c.1587G>T p.V529= | Silent (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- EIF3K | c.597G>A p.K199= | Silent (SNP) | VAF 30/407 reads (7%) | catalogued as rs1245572770, COSV99942887; called by muse, mutect2
- ENPP3 | c.1770T>C p.N590= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- ERBB4 | c.1836G>T p.R612= | Silent (SNP) | VAF 75/465 reads (16%) | called by muse, mutect2, varscan2
- FCGBP | c.6582C>T p.F2194= | Silent (SNP) | VAF 182/3193 reads (6%) | called by muse, mutect2
- FOLR1 | c.393C>T p.N131= | Silent (SNP) | VAF 106/888 reads (12%) | catalogued as rs61735636, COSV56616714; ClinVar: likely benign; called by muse, mutect2, varscan2
- FZR1 | c.1206G>T p.V402= | Silent (SNP) | VAF 58/271 reads (21%) | called by muse, mutect2, varscan2
- GALNTL6 | c.693G>A p.L231= | Silent (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- GAS2 | c.237G>A p.K79= | Silent (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- GHSR | c.324C>G p.P108= | Silent (SNP) | VAF 104/1132 reads (9%) | catalogued as rs1190330659; called by muse, mutect2
- GIPC1 | c.978G>A p.G326= | Silent (SNP) | VAF 42/223 reads (19%) | called by muse, mutect2, varscan2
- GRM1 | c.138C>T p.I46= | Silent (SNP) | VAF 78/477 reads (16%) | catalogued as COSV51256841; called by muse, mutect2, varscan2
- H1-4 | c.330G>A p.K110= | Silent (SNP) | VAF 99/599 reads (17%) | called by muse, mutect2, varscan2
- HDAC4 | c.2511G>C p.V837= | Silent (SNP) | VAF 81/521 reads (16%) | called by muse, mutect2, varscan2
- HDLBP | c.1887C>T p.I629= | Silent (SNP) | VAF 54/273 reads (20%) | called by muse, mutect2, varscan2
- HSF2 | c.999C>T p.S333= | Silent (SNP) | VAF 53/327 reads (16%) | called by muse, mutect2, varscan2
- HTR1F | c.795G>T p.V265= | Silent (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.72C>T p.I24= | Silent (SNP) | VAF 52/496 reads (10%) | called by muse, mutect2, varscan2
- IMPA2 | c.291G>A p.T97= | Silent (SNP) | VAF 66/406 reads (16%) | catalogued as rs748365198, COSV52319285, COSV52319358; called by muse, mutect2, varscan2
- KCNQ3 | c.1521C>A p.P507= | Silent (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- KIF3C | c.294G>A p.Q98= | Silent (SNP) | VAF 61/338 reads (18%) | called by muse, mutect2, varscan2
- KMT5C | c.756A>G p.P252= | Silent (SNP) | VAF 84/468 reads (18%) | called by muse, mutect2, varscan2
- KRT85 | c.219C>G p.A73= | Silent (SNP) | VAF 59/357 reads (17%) | catalogued as rs770105838, COSV99225488; called by muse, mutect2, varscan2
- KRTAP4-6 | c.348C>G p.R116= | Silent (SNP) | VAF 93/793 reads (12%) | called by muse, mutect2, varscan2
- LRFN5 | c.2070C>A p.P690= | Silent (SNP) | VAF 37/282 reads (13%) | catalogued as COSV53271991; called by muse, mutect2, varscan2
- LRP1B | c.12358A>C p.R4120= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, varscan2
- LRRC9 | c.2895C>T p.L965= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1497A>T p.G499= | Silent (SNP) | VAF 85/251 reads (34%) | called by muse, mutect2, varscan2
- MAPT | c.1320G>T p.G440= (on ENST00000262410 / NM_001377265.1; = p.G365= on NM_016835.4) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV52247939; called by mutect2, varscan2
- MMP25 | c.243A>T p.T81= | Silent (SNP) | VAF 44/345 reads (13%) | called by muse, mutect2, varscan2
- NBN | c.72C>T p.Y24= | Silent (SNP) | VAF 32/272 reads (12%) | catalogued as rs1001590969; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEB | c.6678G>A p.K2226= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as rs755634045, CD1413985; called by muse, mutect2, varscan2
- NF1 | c.8142T>C p.F2714= (on ENST00000358273 / NM_001042492.3; = p.F2693= on NM_000267.3) | Silent (SNP) | VAF 53/382 reads (14%) | called by muse, mutect2, varscan2
- NPTX2 | c.768G>A p.L256= | Silent (SNP) | VAF 79/374 reads (21%) | catalogued as rs1240151401; called by muse, mutect2, varscan2
- NUGGC | c.2322G>A p.R774= | Silent (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- OR14A2 | c.516T>A p.I172= | Silent (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- OR4M1 | c.69C>G p.V23= | Silent (SNP) | VAF 22/242 reads (9%) | catalogued as COSV60059477, COSV60062291; called by muse, mutect2
- OR51B4 | c.591T>A p.I197= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- OR5J2 | c.129G>T p.L43= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as COSV56621150; called by muse, mutect2, varscan2
- OTULIN | c.729A>G p.L243= | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as rs925842281; called by muse, mutect2, varscan2
- PAK1 | c.879A>G p.G293= | Silent (SNP) | VAF 170/398 reads (43%) | called by muse, mutect2, varscan2
- PATL1 | c.807A>G p.G269= | Silent (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- PCSK5 | c.1500C>T p.R500= | Silent (SNP) | VAF 30/255 reads (12%) | called by muse, mutect2, varscan2
- PIKFYVE | c.5664C>T p.L1888= | Silent (SNP) | VAF 30/247 reads (12%) | catalogued as rs769755659; called by muse, mutect2, varscan2
- PRG4 | c.2817A>G p.K939= | Silent (SNP) | VAF 142/513 reads (28%) | called by muse, mutect2, varscan2
- PRKCA | c.1491C>G p.T497= | Silent (SNP) | VAF 13/219 reads (6%) | catalogued as COSV99434123; called by muse, mutect2
- PSG11 | c.583C>T p.L195= | Silent (SNP) | VAF 225/1092 reads (21%) | called by muse, mutect2, varscan2
- PTPRT | c.3321A>G p.E1107= | Silent (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- RAD51B | c.1092T>C p.N364= | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- RAG2 | c.1545T>C p.T515= | Silent (SNP) | VAF 51/227 reads (22%) | called by muse, mutect2, varscan2
- RBM26 | c.765T>C p.I255= | Silent (SNP) | VAF 40/314 reads (13%) | called by muse, mutect2, varscan2
- RELN | c.2202C>A p.V734= | Silent (SNP) | VAF 113/610 reads (19%) | called by muse, mutect2, varscan2
- RPL3 | c.555G>T p.V185= | Silent (SNP) | VAF 58/353 reads (16%) | called by muse, mutect2, varscan2
- RRM1 | c.1881C>T p.R627= | Silent (SNP) | VAF 32/195 reads (16%) | called by muse, mutect2, varscan2
- RXYLT1 | c.1107C>T p.H369= | Silent (SNP) | VAF 61/401 reads (15%) | catalogued as rs746733953; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC61A1 | c.699G>A p.A233= | Silent (SNP) | VAF 26/220 reads (12%) | catalogued as rs780054083, COSV99684953; called by mutect2, varscan2
- SHANK2 | c.3960C>T p.D1320= | Silent (SNP) | VAF 90/2856 reads (3%) | catalogued as rs782053793; ClinVar: uncertain significance; called by muse, mutect2
- SIPA1L2 | c.3273G>C p.P1091= | Silent (SNP) | VAF 57/391 reads (15%) | catalogued as COSV53386984; called by muse, mutect2, varscan2
- SLC12A7 | c.1818C>T p.N606= | Silent (SNP) | VAF 68/243 reads (28%) | called by muse, mutect2, varscan2
- SLC4A4 | c.36C>G p.S12= | Silent (SNP) | VAF 57/375 reads (15%) | called by muse, mutect2, varscan2
- SLC5A5 | c.993C>T p.D331= | Silent (SNP) | VAF 118/753 reads (16%) | catalogued as rs1033522902; called by muse, mutect2, varscan2
- SMG1 | c.9642C>T p.A3214= | Silent (SNP) | VAF 48/260 reads (18%) | called by muse, mutect2, varscan2
- SMG1 | c.9372G>A p.K3124= | Silent (SNP) | VAF 47/294 reads (16%) | called by muse, mutect2, varscan2
- SPATA16 | c.159T>A p.G53= | Silent (SNP) | VAF 23/205 reads (11%) | called by muse, mutect2, varscan2
- SPTBN5 | c.8250G>T p.G2750= | Silent (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- TDP2 | c.195G>A p.P65= | Silent (SNP) | VAF 47/238 reads (20%) | called by muse, mutect2, varscan2
- TDRD5 | c.1620G>A p.K540= | Silent (SNP) | VAF 130/441 reads (29%) | called by muse, mutect2, varscan2
- TENM3 | c.1362G>C p.L454= | Silent (SNP) | VAF 40/233 reads (17%) | called by muse, mutect2, varscan2
- TMEM200C | c.1092C>G p.R364= | Silent (SNP) | VAF 101/338 reads (30%) | called by muse, mutect2, varscan2
- TRPM3 | c.1122G>T p.L374= (on ENST00000357533 / NM_001366142.2; = p.L219= on NM_020952.6) | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- TSHZ3 | c.309G>T p.T103= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV53663630, COSV53686438; called by muse, mutect2, varscan2
- TTC14 | c.525C>T p.N175= | Silent (SNP) | VAF 157/306 reads (51%) | catalogued as COSV56010542; called by muse, mutect2, varscan2
- TUFM | c.222C>A p.T74= | Silent (SNP) | VAF 115/626 reads (18%) | called by mutect2, varscan2
- UGT2B11 | c.672C>T p.F224= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs764699731; called by muse, mutect2, varscan2
- WDPCP | c.993C>A p.V331= | Silent (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- ZAP70 | c.240G>T p.P80= | Silent (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- ZBED5 | c.417A>G p.L139= | Silent (SNP) | VAF 25/140 reads (18%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.939C>A p.S313= | Silent (SNP) | VAF 60/301 reads (20%) | catalogued as COSV54297388; called by muse, mutect2, varscan2
- ZIC1 | c.102C>A p.G34= | Silent (SNP) | VAF 49/490 reads (10%) | catalogued as COSV99292044; called by muse, mutect2, varscan2
- ZIC3 | c.810G>T p.R270= | Silent (SNP) | VAF 71/198 reads (36%) | called by muse, mutect2, varscan2
- ZNF219 | c.1947C>T p.L649= | Silent (SNP) | VAF 23/363 reads (6%) | catalogued as rs1307489596; called by muse, mutect2
- ZNF574 | c.28C>T p.L10= | Silent (SNP) | VAF 79/183 reads (43%) | called by muse, mutect2, varscan2
- ZNF729 | c.1248C>T p.F416= | Silent (SNP) | VAF 34/234 reads (15%) | catalogued as rs749342324; called by muse, varscan2
- ZNF804A | c.2508G>T p.V836= | Silent (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
- ZNF835 | c.894C>T p.R298= | Silent (SNP) | VAF 67/382 reads (18%) | catalogued as rs756722230; called by muse, mutect2, varscan2
- AC011525.1 | n.793C>A | RNA (SNP) | VAF 34/280 reads (12%) | called by muse, mutect2, varscan2
- AC103796.1 | n.148-24902C>G | Intron (SNP) | VAF 52/301 reads (17%) | called by muse, mutect2, varscan2
- AC136759.1 | n.888C>T | RNA (SNP) | VAF 13/83 reads (16%) | catalogued as rs776096567; called by muse, mutect2, varscan2
- ADAM9 | c.673-20C>G | Intron (SNP) | VAF 85/300 reads (28%) | called by muse, mutect2, varscan2
- AK9 | c.3633+33G>T | Intron (SNP) | VAF 19/109 reads (17%) | catalogued as rs745932835; called by muse, mutect2, varscan2
- AP1S1 | c.3+114G>C | Intron (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- APBA2 | c.1524+54G>T | Intron (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2, varscan2
- APCDD1L | c.49+752A>C | Intron (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- ARFIP2 | c.197-61G>A | Intron (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- ATP13A4 | c.60+22del | Intron (DEL) | VAF 65/456 reads (14%) | called by mutect2, pindel, varscan2
- BANP | c.1345-184_1345-183del | Intron (DEL) | VAF 26/147 reads (18%) | called by mutect2, pindel, varscan2
- BLVRA | c.*28G>C | 3'UTR (SNP) | VAF 23/290 reads (8%) | catalogued as COSV99645918; called by muse, mutect2
- CADM1 | chr11:115504445 C>A | 5'Flank (SNP) | VAF 29/155 reads (19%) | catalogued as rs1353014256; called by muse, mutect2, varscan2
- CFAP58 | c.*2C>G | 3'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- CREB5 | chr7:28410036 G>T | 5'Flank (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- CWC27 | c.938+3350G>A | Intron (SNP) | VAF 15/108 reads (14%) | catalogued as rs998899206; called by muse, mutect2, varscan2
- DPAGT1 | c.161+47G>A | Intron (SNP) | VAF 60/226 reads (27%) | catalogued as rs746937498; called by muse, mutect2, varscan2
- EARS2 | c.140-767G>A | Intron (SNP) | VAF 10/104 reads (10%) | catalogued as rs1015632041; called by muse, mutect2, varscan2
- EMC3-AS1 | n.515C>T | RNA (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- FAM90A20P | n.634C>T | RNA (SNP) | VAF 130/559 reads (23%) | catalogued as rs749103714; called by muse, mutect2, varscan2
- FGFR1 | c.-28G>A | 5'UTR (SNP) | VAF 84/347 reads (24%) | called by muse, mutect2, varscan2
- FKBP1A | c.37+17_38-34del | Intron (DEL) | VAF 67/392 reads (17%) | called by mutect2, pindel
- GPSM3 | c.-27C>G | 5'UTR (SNP) | VAF 18/95 reads (19%) | catalogued as rs749931097; called by muse, mutect2, varscan2
- GYPB | c.175+55C>A | Intron (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+1263C>A | Intron (SNP) | VAF 62/346 reads (18%) | called by muse, mutect2, varscan2
- HERC2P3 | n.133A>G | RNA (SNP) | VAF 39/331 reads (12%) | called by muse, mutect2, varscan2
- HSPG2 | c.2617+79G>T | Intron (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.711+37C>T | Intron (SNP) | VAF 60/2085 reads (3%) | called by muse, mutect2
- ITIH3 | c.1907-18C>G | Intron (SNP) | VAF 45/177 reads (25%) | called by muse, mutect2, varscan2
- KCNH6 | chr17:63523400 G>T | 5'Flank (SNP) | VAF 36/192 reads (19%) | called by muse, mutect2, varscan2
- KCNQ4 | c.*8C>T | 3'UTR (SNP) | VAF 64/333 reads (19%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6471A>G | Intron (SNP) | VAF 62/290 reads (21%) | called by muse, mutect2, varscan2
- LINC02649 | n.58C>G | RNA (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- MACF1 | c.-70C>A | 5'UTR (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5750C>G | Intron (SNP) | VAF 88/812 reads (11%) | called by muse, mutect2, varscan2
- MED21 | c.42+117C>T | Intron (SNP) | VAF 26/124 reads (21%) | catalogued as rs774997051; called by muse, mutect2, varscan2
- METTL22 | c.*426G>T | 3'UTR (SNP) | VAF 73/435 reads (17%) | called by muse, mutect2, varscan2
- MFSD4B | c.*247G>A | 3'UTR (SNP) | VAF 29/157 reads (18%) | catalogued as rs1245109361, COSV100920608; called by muse, mutect2, varscan2
- MIR373 | n.35C>T | RNA (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- MIR622 | n.22G>T | RNA (SNP) | VAF 94/226 reads (42%) | catalogued as rs1477669704; called by muse, mutect2, varscan2
- MKLN1 | c.2086+73G>A | Intron (SNP) | VAF 21/98 reads (21%) | catalogued as rs369484648; called by muse, mutect2, varscan2
- MYPN | c.*523A>G | 3'UTR (SNP) | VAF 100/480 reads (21%) | called by muse, mutect2, varscan2
- NWD1 | c.198+1506T>A | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53402T>C | Intron (SNP) | VAF 76/339 reads (22%) | catalogued as rs1432603782; called by muse, mutect2, varscan2
- OSMR | c.1585+280C>T | Intron (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- PDIA3P1 | chr1:147179174 A>T | 3'Flank (SNP) | VAF 151/449 reads (34%) | called by muse, mutect2, varscan2
- PPP1R14A | c.*3C>T | 3'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- RARRES1 | c.-8C>G | 5'UTR (SNP) | VAF 65/693 reads (9%) | called by muse, mutect2
- REG1B | c.-12C>A | 5'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- RNASET2 | c.446+121T>C | Intron (SNP) | VAF 52/364 reads (14%) | called by muse, mutect2, varscan2
- RPL37 | c.-23C>A | 5'UTR (SNP) | VAF 58/424 reads (14%) | catalogued as COSV99947697; called by muse, mutect2, varscan2
- SERHL2 | c.329-99A>G | Intron (SNP) | VAF 7/43 reads (16%) | called by mutect2, varscan2
- SERHL2 | c.329-98T>C | Intron (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- SFRP1 | c.544+1791C>T | Intron (SNP) | VAF 77/351 reads (22%) | called by muse, mutect2, varscan2
- SKP1P2 | n.381C>A | RNA (SNP) | VAF 77/249 reads (31%) | called by muse, mutect2, varscan2
- SNRPN | c.4-428G>A | Intron (SNP) | VAF 20/115 reads (17%) | catalogued as rs1324565169; called by muse, mutect2, varscan2
- SNX2 | c.1438-12G>T | Intron (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-2416G>A | Intron (SNP) | VAF 34/135 reads (25%) | catalogued as rs1441511366; called by muse, mutect2, varscan2
- SSPOP | n.8678C>T | RNA (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.12169G>T | RNA (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- STAB2 | c.2086-37G>T | Intron (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
- TAAR3P | n.684C>G | RNA (SNP) | VAF 34/238 reads (14%) | called by muse, mutect2, varscan2
- TRIM51EP | n.763A>T | RNA (SNP) | VAF 97/675 reads (14%) | called by muse, mutect2, varscan2
- UMPS | c.*5050G>C | 3'UTR (SNP) | VAF 59/362 reads (16%) | catalogued as rs1258387061; called by muse, mutect2, varscan2
- VEGFB | c.-29_-28insT | 5'UTR (INS) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- VPS13A | c.9189+267A>C | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1058G>T | 3'UTR (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- XPO5 | c.2160+196C>A | Intron (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
